Surgical pathology report (de-identified scan), TCGA case TCGA-2Z-A9JL, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Z-A9JL-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

ICD-O.3

Carcinoma, papillary
renal cell 8260/3

Site: @ Kidney NOS C64.9
J 4/28/14

Final Diagnosis

- A. RIGHT KIDNEY, PARTIAL NEPHRECTOMY:
Renal cell carcinoma, papillary type 1.
See Key Pathological Findings and Comment.
- B. RIGHT KIDNEY, DEEP MARGIN:
Benign renal parenchyma.

I, _____ the attending pathologist, personally reviewed all slides
and / or materials and rendered the final diagnosis. Electronically signed
out by _____

Comment

Immunoperoxidase stains performed on block A3 show the tumor cells positive for vimentin, CK7,
AMACR, AE1/AE3, CAM5.2, EMA and focally positive for CD10.

Key Pathological Findings

A: Kidney Resection

PROCEDURE:

Partial nephrectomy

SPECIMEN LATERALITY:

Right

TUMOR SITE:

Not specified

TUMOR SIZE (largest tumor if multiple):

Dimension: 1.7 cm

TUMOR FOCALITY:

Unifocal

MACROSCOPIC EXTENT OF TUMOR:

Tumor limited to kidney

HISTOLOGIC TYPE:

Papillary renal cell carcinoma

SARCOMATOID FEATURES:

Not identified

TUMOR NECROSIS:

Not identified

HISTOLOGIC GRADE (Fuhrman Nuclear Grade):

G2: Nuclei slightly irregular, approximately 15 microns; nucleoli evident

PATTERN OF GROWTH:

[page 2 of 3]
Papillary
MICROSCOPIC TUMOR EXTENSION:
Tumor limited to kidney
MARGINS:
Margins uninvolved by carcinoma
ANGIOLYMPHATIC INVASION:
Absent
PRIMARY TUMOR (pT):
pT1a: Tumor 4 cm or less in greatest dimension, limited to the kidney
REGIONAL LYMPH NODES (pN):
pNX: Regional lymph nodes cannot be assessed
DISTANT METASTASIS (pM):
pMX
PATHOLOGIC FINDINGS IN NONNEOPLASTIC KIDNEY:
Insufficient tissue (partial nephrectomy specimen with <5 mm of adjacent nonneoplastic kidney)

Specimen(s) Received

A RIGHT PARTIAL NEPHRECTOMY FS
B DEEP MARGIN FS

Clinical History

None given.

Preoperative Diagnosis

Right renal mass.

Intraoperative Consultation

FSA1. RIGHT PARTIAL NEPHRECTOMY:
Papillary tumor, focally extending to inked margin.

FSB1. DEEP MARGIN:
Margin negative.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by Dr.

I, _____, have performed the intraoperative consultations and issued the above diagnosis.

Gross Description

A. The specimen is received fresh. Part A labeled "right partial nephrectomy, ink is margin". The specimen consists of a partial nephrectomy which measures 2 x 1.8 x 1.6 cm. Prior to sectioning the specimen is inked as follows:

Blue: Renal capsule
Black: Parenchymal resection margin.

[page 3 of 3]
The specimen is serially sectioned to reveal an irregular to roughly ovoid, ill-defined, rubbery intraparenchymal tumor which measures 1.7 x 1.5 x 1.3 cm. The tumor bulges capsule and extends to within less than 0.1 cm of the closest parenchymal resection margin. The cut surface of the tumor is variegated, pale-yellow to pink, focally hemorrhagic. No foci of necrosis are grossly identified. Representative sections of the specimen are submitted to the Tissue Procurement Laboratory. Representative section of the tumor in relation to the closest inked black parenchymal resection margin is submitted for frozen section as FSA1. The remainder of the specimen is serially sectioned and submitted entirely in 6 cassettes, A2-A7.

B. Part B labeled "deep margin, ink is margin". The specimen consists of an irregular, oriented fragment of tan-brown renal parenchyma measuring 1.5 x 0.5 x 0.2 cm. Prior to sectioning the total resection margin is inked black. The specimen is bisected and submitted entirely for frozen section as FSB1.

Source: NCI Genomic Data Commons file 53b25c5d-fa25-4f40-b541-46d68d28dafe (TCGA-2Z-A9JL.16F7804A-4A67-4B7C-9657-903F2124012E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).